Somatic mutation profile of tumor specimen HCM-CSHL-0085-C24-86M (aliquot HCM-CSHL-0085-C24-86M-01D-A937-36) from HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9284ed17-f649-404d-a0d7-a8ba4a6dbec8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0085-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0085-C24-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04bbf77f-fabc-4c21-9196-3e680751fb7a

The open-access MAF lists 131 somatic variants for this specimen: 92 protein-altering or splice-affecting, 31 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 31, Nonsense Mutation 3, Splice Region 3, RNA 3, Translation Start Site 2, Intron 2, 3'UTR 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 232/470 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 325/517 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV51552966; called by muse, mutect2, varscan2
- ADGRB1 | c.2202G>A p.A734= | Splice Region (SNP) | VAF 117/271 reads (43%) | catalogued as rs753558928; called by muse, mutect2, varscan2
- ADGRB1 | c.4604G>A p.R1535Q | Missense Mutation (SNP) | VAF 240/495 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV60097426; called by muse, mutect2, varscan2
- AIM2 | c.442G>T p.G148W | Missense Mutation (SNP) | VAF 178/518 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100931079; called by muse, mutect2, varscan2
- ANK2 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 169/336 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); catalogued as rs1238418730; called by muse, mutect2, varscan2
- ARID2 | c.1352del p.S451Lfs*12 | Frame Shift Del (DEL) | VAF 223/307 reads (73%) | catalogued as COSV57600163; called by mutect2, pindel, varscan2
- CALHM2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 260/512 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.322); catalogued as rs377104588; called by muse, mutect2, varscan2
- CLTCL1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 113/358 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs1555966213; called by muse, mutect2, varscan2
- CSN1S1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs372612450, COSV55891851; called by muse, mutect2, varscan2
- DACT3 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 168/627 reads (27%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.564); catalogued as rs1267678211; called by muse, mutect2, varscan2
- EPHA1 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 136/294 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767930814; called by muse, mutect2, varscan2
- ESPNL | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 230/484 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs927691376; called by muse, mutect2, varscan2
- FAM47A | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867589029, COSV60496026; called by muse, varscan2
- FCGRT | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 93/452 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV54543655; called by muse, mutect2, varscan2
- FERD3L | c.97T>G p.F33V | Missense Mutation (SNP) | VAF 237/503 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV51761712; called by muse, mutect2, varscan2
- FSTL5 | c.1507_1508dup p.W503Cfs*37 | Frame Shift Ins (INS) | VAF 162/338 reads (48%) | catalogued as COSV60196626; called by mutect2, varscan2
- HCAR3 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 269/918 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs368546949; called by muse, mutect2, varscan2
- HOGA1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 211/418 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs754634699, COSV65706481; called by muse, mutect2, varscan2
- ICAM5 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 207/435 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55748939; called by muse, mutect2, varscan2
- ITCH | c.1970C>T p.T657M (on ENST00000262650 / NM_001257137.3; = p.T616M on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/499 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445655265, COSV52933847; called by muse, mutect2, varscan2
- KLHL1 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 204/405 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748882149, COSV64769060, COSV64786398; called by muse, mutect2, varscan2
- LRRTM4 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 265/267 reads (99%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV69142997; called by muse, mutect2, varscan2
- MAGEE1 | c.2398A>G p.T800A | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.929); catalogued as rs781960739; called by muse, mutect2, varscan2
- MCRIP1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 211/425 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754717613; called by muse, mutect2, varscan2
- NBEA | c.2118A>G p.I706M | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1365413222; called by muse, mutect2, varscan2
- OR2J2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 270/547 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755187820; called by muse, mutect2, varscan2
- OR4A16 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 513/514 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV59042819; called by muse, mutect2, varscan2
- P2RY14 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 159/318 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV56391075; called by muse, mutect2, varscan2
- PABPC3 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 176/390 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs773025278, COSV99879495; called by muse, varscan2
- PARP10 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 175/368 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs782649313, COSV57299228; called by muse, mutect2, varscan2
- PCDHB15 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 211/409 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as rs1554292027; called by muse, mutect2, varscan2
- PLEKHM3 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 421/421 reads (100%) | catalogued as rs1447181721; called by muse, mutect2, varscan2
- PLXND1 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 254/544 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs554042254; called by muse, mutect2, varscan2
- PRR23A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV67214028; called by muse, varscan2
- RAD50 | c.1892A>C p.D631A | Missense Mutation (SNP) | VAF 218/448 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1372866109; called by muse, mutect2, varscan2
- RYR3 | c.13120C>T p.R4374W (on ENST00000389232; = p.R4375W on NM_001036.6) | Missense Mutation (SNP) | VAF 227/651 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759909362, COSV66778249; called by muse, mutect2, varscan2
- SIRPB1 | c.432C>T p.R144= | Splice Region (SNP) | VAF 160/615 reads (26%) | catalogued as rs200840558, COSV53537445; called by muse, mutect2, varscan2
- SRD5A1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57014835; called by muse, mutect2, varscan2
- TDRD9 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 128/289 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.132); catalogued as rs142470189; called by muse, mutect2, varscan2
- TENM2 | c.5119G>A p.E1707K (on ENST00000518659 / NM_001122679.2; = p.E1468K on NM_001080428.3) | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs781107567, COSV101319462; called by muse, mutect2, varscan2
- TMEM63C | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 185/407 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs374759104; called by muse, mutect2, varscan2
- TPTE2 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV55023847; called by muse, mutect2, varscan2
- TRDN | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 147/337 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1371219098, COSV100522147; called by muse, mutect2, varscan2
- TTN | c.31129G>A p.A10377T (on ENST00000591111; = p.A9450T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 221/222 reads (100%) | PolyPhen benign (0.025); catalogued as rs756672871; called by muse, mutect2, varscan2
- UNC5C | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 190/419 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs142722408; called by muse, mutect2, varscan2
- ZSCAN9 | c.987G>C p.Q329H | Missense Mutation (SNP) | VAF 256/473 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.378); catalogued as COSV99356463; called by muse, mutect2, varscan2
- ACO1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ANK2 | c.2694-4C>T | Splice Region (SNP) | VAF 117/242 reads (48%) | called by muse, mutect2, varscan2
- AP5M1 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 356/356 reads (100%) | called by muse, mutect2, varscan2
- ARID1A | c.4984A>T p.K1662* | Nonsense Mutation (SNP) | VAF 280/280 reads (100%) | called by muse, mutect2, varscan2
- ASCL3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CASZ1 | c.4629C>G p.I1543M | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCDC141 | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 278/278 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH12 | c.1967A>C p.N656T | Missense Mutation (SNP) | VAF 166/347 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CIB1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 188/668 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CSMD1 | c.10466T>A p.V3489E (on ENST00000520002; = p.V3488E on NM_033225.6) | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CUL4A | c.1858+1G>T p.X620_splice (on ENST00000375440 / NM_001008895.4; = p.X520_splice on NM_003589.3) | Splice Site (SNP) | VAF 156/295 reads (53%) | called by muse, mutect2, varscan2
- DCLK1 | c.1944+2T>G p.X648_splice | Splice Site (SNP) | VAF 162/317 reads (51%) | called by muse, mutect2, varscan2
- DCLK1 | c.1418T>A p.L473H | Missense Mutation (SNP) | VAF 139/279 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX33 | c.1327A>G p.M443V | Missense Mutation (SNP) | VAF 128/275 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESF1 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 364/540 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR75 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 458/460 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- HILPDA | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 145/275 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN2 | c.12859G>C p.E4287Q | Missense Mutation (SNP) | VAF 206/403 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- IGKV2-24 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IPO7 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 269/270 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KNDC1 | c.3543G>C p.R1181S | Missense Mutation (SNP) | VAF 159/575 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- LRRC66 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NRDC | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 374/375 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PHKG1 | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 119/269 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PIP5K1C | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 188/432 reads (44%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLK2 | c.1051G>C p.V351L | Missense Mutation (SNP) | VAF 346/347 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PPP1R3A | c.2363G>T p.C788F | Missense Mutation (SNP) | VAF 139/339 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKDC | c.1068_1070del p.N356del | In Frame Del (DEL) | VAF 128/271 reads (47%) | called by pindel, varscan2
- PTGER3 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 281/551 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS20 | c.559G>A p.A187T (on ENST00000297313 / NM_170587.4; = p.A40T on NM_003702.4) | Missense Mutation (SNP) | VAF 284/571 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, varscan2
- RNF6 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 146/529 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- RYR3 | c.6783A>C p.Q2261H | Missense Mutation (SNP) | VAF 122/396 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEMA3A | c.1003T>G p.F335V | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SF3A3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 356/357 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC6A4 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 402/402 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCF20 | c.2605G>T p.D869Y | Missense Mutation (SNP) | VAF 194/560 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPA1 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TTN | c.56612A>C p.K18871T (on ENST00000591111; = p.K11447T on NM_003319.4) | Missense Mutation (SNP) | VAF 415/416 reads (100%) | PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- XYLT2 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 574/576 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZBTB16 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZDHHC6 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 379/577 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF365 | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 152/638 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF385D | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 151/295 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZSCAN29 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 354/578 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ZSWIM2 | c.1479T>A p.F493L | Missense Mutation (SNP) | VAF 75/280 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKIRIN1 | c.393A>G p.T131= | Silent (SNP) | VAF 166/349 reads (48%) | catalogued as rs1298893257; called by muse, mutect2, varscan2
- ALPK2 | c.3045C>T p.T1015= | Silent (SNP) | VAF 174/174 reads (100%) | catalogued as rs541753586; called by muse, mutect2, varscan2
- ANKRD1 | c.657C>A p.L219= | Silent (SNP) | VAF 155/306 reads (51%) | catalogued as COSV100865362; called by muse, mutect2, varscan2
- ARPP21 | c.1317A>G p.A439= | Silent (SNP) | VAF 221/453 reads (49%) | catalogued as COSV51806064; called by muse, mutect2, varscan2
- ASCL3 | c.18C>T p.G6= | Silent (SNP) | VAF 118/264 reads (45%) | catalogued as COSV100366920; called by muse, mutect2, varscan2
- BAHCC1 | c.5625G>A p.S1875= | Silent (SNP) | VAF 269/554 reads (49%) | catalogued as rs371234536; called by muse, mutect2, varscan2
- C3AR1 | c.183C>T p.F61= | Silent (SNP) | VAF 226/461 reads (49%) | called by muse, mutect2, varscan2
- CCDC160 | c.582G>A p.T194= | Silent (SNP) | VAF 320/320 reads (100%) | catalogued as rs751796060, COSV66251327; called by muse, mutect2, varscan2
- CLCA1 | c.1791G>A p.T597= | Silent (SNP) | VAF 220/475 reads (46%) | catalogued as rs899149911, COSV52327435; called by muse, mutect2, varscan2
- DDX3X | c.228T>C p.D76= (on ENST00000399959; = p.D77= on NM_001356.5) | Silent (SNP) | VAF 215/215 reads (100%) | called by muse, mutect2, varscan2
- DEPDC5 | c.2256G>T p.L752= (on ENST00000400246; = p.L821= on NM_014662.5) | Silent (SNP) | VAF 306/447 reads (68%) | called by muse, mutect2, varscan2
- FAM209A | c.447G>A p.K149= | Silent (SNP) | VAF 581/812 reads (72%) | called by muse, mutect2, varscan2
- FAT4 | c.10095A>C p.R3365= | Silent (SNP) | VAF 199/391 reads (51%) | called by muse, mutect2, varscan2
- FZD8 | c.1923C>T p.G641= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- GRIN1 | c.114C>T p.H38= | Silent (SNP) | VAF 257/508 reads (51%) | catalogued as rs1241572680, COSV59300354; called by muse, mutect2, varscan2
- HDAC7 | c.1980T>C p.G660= (on ENST00000427332; = p.G699= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 378/379 reads (100%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.228C>T p.I76= | Silent (SNP) | VAF 108/373 reads (29%) | catalogued as rs368264920; called by muse, mutect2, varscan2
- IL4 | c.147C>T p.T49= | Silent (SNP) | VAF 163/370 reads (44%) | catalogued as rs759103191; called by muse, mutect2, varscan2
- KRT5 | c.75G>A p.P25= | Silent (SNP) | VAF 243/487 reads (50%) | catalogued as rs572849401; called by muse, mutect2, varscan2
- MDGA2 | c.372A>T p.G124= | Silent (SNP) | VAF 293/293 reads (100%) | called by muse, mutect2, varscan2
- OR56B4 | c.810G>A p.E270= | Silent (SNP) | VAF 474/478 reads (99%) | called by muse, mutect2, varscan2
- PAXIP1 | c.2868C>T p.F956= | Silent (SNP) | VAF 188/362 reads (52%) | called by muse, mutect2, varscan2
- PROM1 | c.2094C>T p.S698= | Silent (SNP) | VAF 118/165 reads (72%) | catalogued as rs199727800, CM1312881; called by muse, mutect2, varscan2
- RFPL4A | c.720A>G p.T240= | Silent (SNP) | VAF 186/1721 reads (11%) | catalogued as rs757162286; called by muse, mutect2, varscan2
- RFPL4AL1 | c.720A>G p.T240= | Silent (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- SLC22A23 | c.1164G>A p.Q388= | Silent (SNP) | VAF 128/262 reads (49%) | catalogued as rs768889057; called by muse, mutect2, varscan2
- SYDE1 | c.819C>T p.Y273= | Silent (SNP) | VAF 347/686 reads (51%) | catalogued as rs1413962871; called by muse, mutect2, varscan2
- TFEB | c.37C>A p.R13= | Silent (SNP) | VAF 299/575 reads (52%) | catalogued as COSV57824244; called by muse, mutect2, varscan2
- TRPM8 | c.2286G>A p.S762= | Silent (SNP) | VAF 453/454 reads (100%) | catalogued as rs199933698, COSV61222637; called by muse, mutect2, varscan2
- UBE3A | c.1372C>T p.L458= | Silent (SNP) | VAF 128/420 reads (30%) | called by muse, mutect2, varscan2
- ZWILCH | c.1020C>T p.F340= | Silent (SNP) | VAF 186/369 reads (50%) | catalogued as rs769354705; called by muse, mutect2, varscan2
- HAS1 | c.10-25C>T | Intron (SNP) | VAF 94/416 reads (23%) | catalogued as rs1225187612; called by muse, mutect2, varscan2
- KRT6B | c.*11C>T | 3'UTR (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- LEPR | c.-120C>G | 5'UTR (SNP) | VAF 348/348 reads (100%) | called by muse, mutect2, varscan2
- OR4N3P | n.687T>G | RNA (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- PARGP1 | n.1966C>T | RNA (SNP) | VAF 98/333 reads (29%) | catalogued as rs1374034744; called by muse, mutect2, varscan2
- UBTFL2 | n.483A>G | RNA (SNP) | VAF 273/277 reads (99%) | catalogued as rs1433232626; called by muse, mutect2, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 26/182 reads (14%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
- ZNF589 | c.97-3971G>A | Intron (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
